Gene-level copy-number profile of tumor specimen TCGA-23-2643-01A from TCGA case TCGA-23-2643, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 74.2 years (27,093 days).
Specimen TCGA-23-2643-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.008c0e5f-0fd9-447e-a77c-afc20cb109e6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-23-2643-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/576facf6-72c9-41c5-bafe-f66a0a83813f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,395; copy number 2: 24,891; copy number 3: 14,873; copy number 4: 12,518; copy number 5: 3,162; copy number 6: 1,118; copy number 7: 155; copy number 8: 245; copy number 9: 46; copy number 10: 78; copy number 11: 175; copy number 16: 19; copy number 18: 42; copy number 19: 100.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-23-2643-01A-01D-1043-01): tumor purity 0.84, ploidy 2.96, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,140 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:31,790,422–33,431,052, 70 genes, copy number 6–8 (within-gene range 3–8) (broad region; genes not listed).
- chr1:35,720,218–46,516,216, 359 genes, copy number 7–19 (within-gene range 2–19) (broad region; genes not listed).
- chr1:63,774,017–64,181,498, 1 gene, copy number 6 (within-gene range 1–6): ROR1.
- chr1:64,028,894–64,267,368, 5 genes, copy number 6: RNU6-809P, Y_RNA, ROR1-AS1, AL445205.1, UBE2U.
- chr1:68,098,473–68,233,120, 1 gene, copy number 8 (within-gene range 3–8): WLS.
- chr1:68,183,518–68,449,954, 6 genes, copy number 8: MIR1262, RPS7P4, COX6B1P7, ELOCP18, AL139413.1, RPE65.
- chr1:69,567,922–70,151,945, 1 gene, copy number 5 (within-gene range 3–5): LRRC7.
- chr1:69,879,592–70,385,339, 10 genes, copy number 5: RN7SL538P, PIN1P1, LRRC7-AS1, LRRC40, RN7SL242P, SRSF11, AL353771.1, ANKRD13C, HHLA3, HHLA3-AS1.
- chr1:75,202,131–75,932,404, 13 genes, copy number 6 (within-gene range 2–6): SLC44A5, AC093156.1, RNU6-503P, AL096829.1, AL137803.1, ACADM, DLSTP1, RABGGTB, SNORD45C, SNORD45A, SNORD45B, MSH4, ASB17.
- chr1:86,288,704–90,533,472, 77 genes, copy number 7–16 (broad region; genes not listed).
- chr3:91,356,755–144,445,844, 869 genes, copy number 5 (broad region; genes not listed).
- chr3:146,921,795–146,927,429, 1 gene, copy number 10: LINC02010.
- chr3:149,517,235–151,080,726, 41 genes, copy number 11 (within-gene range 4–11): WWTR1, RNU6-1098P, WWTR1-IT1, WWTR1-AS1, COMMD2, ANKUB1, RNU6-507P, RNF13, RNU6-720P, NPM1P29, PFN2, AC117395.1, TMEM183B, PPIAP73, HNRNPA1P24, AC117386.2, AC022494.1, LINC01998, RPL32P9, AC117386.1, LINC01213, U2, LINC01214, AC018545.1, TSC22D2, SERP1, EIF2A, SELENOT, AC069236.1, ERICH6, ERICH6-AS1, SNRPCP3, AC011317.1, SIAH2, SIAH2-AS1, CLRN1-AS1, MINDY4B, AC020636.2, AC020636.1, CLRN1, AC108726.1.
- chr3:154,334,943–154,430,190, 1 gene, copy number 5 (within-gene range 3–5): GPR149.
- chr3:154,511,535–157,677,749, 63 genes, copy number 5 (broad region; genes not listed).
- chr3:165,206,929–165,846,519, 2 genes, copy number 7: LINC01322, BCHE.
- chr3:169,003,022–170,085,392, 28 genes, copy number 11: LINC01997, MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3.
- chr3:180,989,762–181,836,880, 1 gene, copy number 5 (within-gene range 3–5): SOX2-OT.
- chr3:181,372,732–185,825,042, 114 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr4:1,056,250–5,893,086, 117 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).
- chr5:58,198–34,832,612, 528 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr8:92,351,912–145,066,685, 859 genes, copy number 5 (broad region; genes not listed).
- chr10:62,682,652–65,315,080, 31 genes, copy number 5: AC067751.1, ALDH7A1P4, ADO, EGR2, RNU6-543P, AL590502.1, NRBF2, JMJD1C, TATDN1P1, AC022022.2, MIR1296, PRELID1P3, JMJD1C-AS1, AC022022.1, REEP3, AC022387.2, MRPL35P2, AC022387.1, AC013287.1, RPL7AP50, AC012558.1, DBF4P1, RPL17P35, CYP2C61P, ANXA2P3, LINC02671, NEK4P3, AL513321.2, MYL6P3, AL513321.1, AL592466.1.
- chr10:111,787,233–115,948,999, 59 genes, copy number 9–10 (within-gene range 3–10): AL136119.1, GPAM, TECTB, MIR6715B, MIR6715A, GUCY2GP, ACSL5, AL157786.1, ZDHHC6, VTI1A, AC022018.1, MIR4295, AL139120.1, AL158212.5, AL158212.3, AL158212.4, AL158212.1, TCF7L2, AL158212.2, RPS15AP30, RNU7-165P, AL133482.1, PPIAP39, HABP2, NRAP, CASP7, AL592546.2, PLEKHS1, MIR4483, AL592546.1, DCLRE1A, NHLRC2, AL592546.3, ADRB1, AC022023.2, RNU6-709P, UBE2V1P5, CCDC186, AC022023.1, MIR2110, TDRD1, VWA2, AURKAP2, AC005383.1, AFAP1L2, RN7SL384P, AL133384.2, ABLIM1, AL133384.1, PPIAP19, AL137025.1, TAF9BP2, FAM160B1, RPL15P13, TRUB1, RNU6-1121P, LINC02626, ATRNL1, AC016042.1.
- chr10:116,538,183–127,553,540, 192 genes, copy number 5–10 (broad region; genes not listed).
- chr10:128,912,810–130,184,521, 20 genes, copy number 5: LINC02667, AL355537.1, AL355537.2, AL391869.1, AL359508.1, MGMT, AL355531.1, AL157832.2, AL157832.1, LINC02666, EBF3, AL354950.2, MIR4297, AL354950.1, AL354950.3, C10orf143, AL139123.1, CTAGE7P, PPIAP32, GLRX3.
- chr10:132,036,336–133,761,125, 71 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr12:66,767–34,249,958, 850 genes, copy number 6 (broad region; genes not listed).
- chr14:42,807,378–43,314,803, 5 genes, copy number 5: YWHAQP1, AL163153.1, TUBBP3, HNRNPUP1, AL583809.1.
- chr21:10,328,411–46,665,124, 745 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,857. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
